Somatic mutation profile of tumor specimen 0DTUYP from CCDI case PBCKIA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.1 years (51 days).
Specimen 0DTUYP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49bd55cf-5645-40e6-8bfb-9cf67f4bbffd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTUX5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d3fed3d-2b7d-4c27-a9d9-c156b5757646

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP9B | c.1916G>A p.R639Q | Missense Mutation (SNP) | VAF 30/546 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs373738625, COSV56951141; called by muse, mutect2
- PEPD | c.1334G>A p.G445D | Missense Mutation (SNP) | VAF 24/726 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2
